Somatic mutation profile of tumor specimen RC-B6SO-TTP1-A (aliquot RC-B6SO-TTP1-A-1-1-D-A94K-47) from RC case RC-B6SO, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Anaplastic large cell lymphoma, T cell and Null cell type; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 47.5 years (17,348 days).
Specimen RC-B6SO-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be5b6a0d-e31d-4079-9e77-437edbc1715f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6SO-NB1-A (Peripheral Blood Components NOS; tissue type Normal), aliquot RC-B6SO-NB1-A-1-0-D-A94K-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e75bccc2-9b0b-45b1-9c66-fb4a6ba67576

The open-access MAF lists 176 somatic variants for this specimen: 110 protein-altering or splice-affecting, 54 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 54, Intron 9, Nonsense Mutation 8, Frame Shift Del 2, RNA 2, In Frame Del 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH6 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs766786197; called by muse, mutect2, varscan2
- ATP2C2 | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV52293969; called by muse, mutect2, varscan2
- ATXN1 | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 28/169 reads (17%) | catalogued as COSV55210656; called by muse, mutect2, varscan2
- ATXN1L | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1202144754; called by muse, mutect2, varscan2
- BCLAF3 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1407478898, COSV61413669; called by muse, mutect2, varscan2
- CDK6 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV56011227; called by muse, mutect2, varscan2
- COL24A1 | c.2852G>A p.G951E | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65301838; called by muse, mutect2, varscan2
- COL4A3 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67413384; called by muse, mutect2, varscan2
- DNAH11 | c.8669T>G p.L2890R | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60948819; called by muse, mutect2, varscan2
- DST | c.6956C>G p.T2319S | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs764234224; called by muse, mutect2, varscan2
- EEF2 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs764015216, COSV100500725; called by muse, mutect2, varscan2
- EEF2 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.408); catalogued as rs145985140; ClinVar: benign; called by muse, mutect2, varscan2
- ERBIN | c.2351C>A p.S784* | Nonsense Mutation (SNP) | VAF 29/153 reads (19%) | catalogued as rs756397256, COSV52324092, COSV52328966; called by muse, mutect2, varscan2
- ERICH6B | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV53917664; called by muse, mutect2
- FBN1 | c.8224G>A p.E2742K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs750199580, CM077252, COSV57310226; ClinVar: uncertain significance; called by muse, mutect2
- FSBP | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.81); catalogued as rs1305292755; called by muse, mutect2, varscan2
- GPC1 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754216019; called by muse, mutect2, varscan2
- GRIN2D | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.038); catalogued as rs1199433797; called by muse, mutect2, varscan2
- H1-7 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100622150, COSV58602196; called by muse, mutect2, varscan2
- HAO1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV66491320; called by muse, mutect2, varscan2
- HS3ST4 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 37/209 reads (18%) | catalogued as COSV100502671; called by muse, mutect2, varscan2
- INAVA | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.757); catalogued as rs768109621; called by muse, mutect2, varscan2
- LAMA5 | c.3245C>T p.P1082L | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs1381384875; called by muse, varscan2
- MAGI1 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100443231; called by muse, mutect2, varscan2
- MARCO | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.914); catalogued as rs527481795; called by muse, mutect2, varscan2
- MBD5 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV68696507; called by muse, mutect2, varscan2
- MBOAT4 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286176051; called by muse, mutect2, varscan2
- MSRA | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs200629688; called by muse, mutect2, varscan2
- PIGZ | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1358034056; called by muse, mutect2, varscan2
- PROSER2 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1564316510; called by muse, mutect2, varscan2
- RHBDD2 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.144); catalogued as rs368476168; called by muse, mutect2, varscan2
- RP1L1 | c.3415G>A p.V1139M | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as rs756527390; called by muse, mutect2
- SHTN1 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53383627; called by muse, mutect2, varscan2
- SLC36A2 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs952943212, COSV100079135; called by muse, mutect2, varscan2
- SLITRK5 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61521791; called by muse, mutect2, varscan2
- SPRY4 | c.437C>T p.P146L (on ENST00000434127 / NM_001127496.3; = p.P169L on NM_030964.4) | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs150116103; called by muse, mutect2, varscan2
- TMEM132D | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV101399773; called by muse, mutect2, varscan2
- WNK2 | c.5480G>A p.R1827Q (on ENST00000297954 / NM_001282394.1; = p.R1790Q on NM_006648.3) | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750788421; called by muse, mutect2
- YRDC | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1375735315; called by muse, mutect2, varscan2
- ACBD7 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ACVR1B | c.497A>G p.D166G | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); called by muse, mutect2
- ADGRF3 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGMO | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BAZ2B | c.488A>T p.N163I | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CDH18 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 26/170 reads (15%) | called by muse, mutect2, varscan2
- CDH2 | c.1160G>A p.W387* | Nonsense Mutation (SNP) | VAF 31/151 reads (21%) | called by muse, mutect2, varscan2
- CDX4 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 56/311 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP47 | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- CHM | c.731A>G p.D244G | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- CLK1 | c.575T>C p.I192T | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL14A1 | c.4460C>T p.P1487L | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- COL4A3 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYB5D2 | c.368A>C p.Y123S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCP2 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH14 | c.9131G>A p.R3044K (on ENST00000445597; = p.R3808K on NM_001367479.1) | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DSC3 | c.1924G>T p.G642* | Nonsense Mutation (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- DST | c.16930G>A p.E5644K (on ENST00000361203 / NM_001374722.1; = p.E3341K on NM_015548.5) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.119); called by muse, mutect2
- DUS4L-BCAP29 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- EFCAB10 | c.185T>A p.F62Y | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EPHB1 | c.1421A>C p.K474T | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- FBN3 | c.346_349+6del p.X116_splice | Splice Site (DEL) | VAF 28/137 reads (20%) | called by mutect2, varscan2
- FBRS | c.715C>T p.R239W (on ENST00000287468; = p.R759W on NM_001105079.3) | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GAREM1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- GPR162 | c.1332_1358del p.Q445_P453del (on ENST00000311268 / NM_019858.2; = p.Q161_P169del on NM_014449.2) | In Frame Del (DEL) | VAF 37/209 reads (18%) | called by mutect2, pindel, varscan2
- H2AC21 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- HAS2 | c.1562G>C p.C521S | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- HCN2 | c.2208G>T p.M736I | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); called by muse, varscan2
- IL15RA | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS5 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- KCTD17 | c.658_678del p.Q220_E226del | In Frame Del (DEL) | VAF 18/145 reads (12%) | called by mutect2, varscan2
- KLHDC1 | c.937A>T p.M313L | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- LAMA1 | c.6806A>T p.K2269I | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); called by mutect2, varscan2
- LAMA1 | c.6804del p.F2268Lfs*10 | Frame Shift Del (DEL) | VAF 17/113 reads (15%) | called by mutect2, pindel, varscan2
- LRRFIP2 | c.2094G>A p.M698I | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- MBD5 | c.554A>T p.E185V | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- MCM10 | c.2557C>T p.P853S (on ENST00000484800 / NM_182751.3; = p.P852S on NM_018518.5) | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MCOLN3 | c.1483A>G p.S495G | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NYAP2 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- OR2A5 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5AN1 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- OSBPL10 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCSK6 | c.1516T>A p.S506T | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PDE1C | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- PHF13 | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- PLA2G2F | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- POLR1B | c.1411T>G p.C471G | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PPP1R17 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PRG4 | c.2519del p.K840Rfs*72 | Frame Shift Del (DEL) | VAF 35/228 reads (15%) | called by mutect2, pindel, varscan2
- RANBP2 | c.8194C>T p.P2732S | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAVER2 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- RFNG | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.056); called by muse, mutect2
- RFX7 | c.3397G>A p.V1133I (on ENST00000559447 / NM_001368074.1; = p.V1230I on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- RYR2 | c.10388C>T p.T3463I | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SECISBP2 | c.1283A>T p.Q428L | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIRPB1 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 30/183 reads (16%) | called by muse, mutect2, varscan2
- SLIT2 | c.239A>C p.H80P | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- SPAG17 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SRGAP2 | c.3003G>T p.K1001N (on ENST00000624873 / NM_001170637.4; = p.K1002N on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- SSX7 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- STON2 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TBRG1 | c.658C>G p.R220G | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX15 | c.7268A>C p.D2423A (on ENST00000256246; = p.D2806A on NM_001350162.2) | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TFDP3 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 63/324 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TNFRSF21 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TRAFD1 | c.1337C>A p.T446N | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2
- TRIM48 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 33/190 reads (17%) | called by muse, mutect2, varscan2
- UGT3A2 | c.287T>A p.F96Y | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VASN | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF546 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF831 | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS13 | c.3684C>T p.R1228= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as rs782126709, COSV52471307; called by muse, mutect2, varscan2
- ADH6 | c.396C>T p.T132= | Silent (SNP) | VAF 29/187 reads (16%) | called by muse, mutect2, varscan2
- AMER3 | c.1540C>A p.R514= | Silent (SNP) | VAF 24/209 reads (11%) | called by muse, mutect2, varscan2
- ANKRD24 | c.822C>T p.S274= | Silent (SNP) | VAF 26/174 reads (15%) | catalogued as rs1328134505; called by muse, mutect2, varscan2
- AP4M1 | c.483G>A p.Q161= | Silent (SNP) | VAF 33/162 reads (20%) | catalogued as rs1203718689, COSV57998579; called by muse, mutect2, varscan2
- BCAR3 | c.1840C>T p.L614= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV53079286; called by muse, mutect2
- BRPF3 | c.1782C>T p.F594= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- C1orf127 | c.2094C>T p.P698= | Silent (SNP) | VAF 51/229 reads (22%) | called by muse, mutect2, varscan2
- CALCB | c.324C>T p.F108= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as rs145827382; called by muse, mutect2, varscan2
- CPED1 | c.2737T>C p.L913= | Silent (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- CYFIP1 | c.963C>A p.T321= | Silent (SNP) | VAF 26/184 reads (14%) | called by muse, mutect2, varscan2
- DAPK1 | c.3618C>T p.I1206= | Silent (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2
- FAT1 | c.270C>T p.L90= | Silent (SNP) | VAF 43/238 reads (18%) | catalogued as rs373265178; called by muse, mutect2, varscan2
- FCMR | c.834G>A p.R278= | Silent (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- GRIN2D | c.2835G>A p.R945= | Silent (SNP) | VAF 21/124 reads (17%) | called by muse, mutect2, varscan2
- HNRNPUL1 | c.846C>T p.V282= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as rs267605500; called by muse, mutect2, varscan2
- KIAA1109 | c.5166T>A p.T1722= | Silent (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2, varscan2
- KLHL1 | c.1941T>A p.G647= | Silent (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- KLHL4 | c.579C>T p.I193= | Silent (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- KMT2D | c.3465G>A p.L1155= | Silent (SNP) | VAF 42/230 reads (18%) | called by muse, mutect2, varscan2
- KRTAP19-8 | c.36C>T p.G12= | Silent (SNP) | VAF 37/163 reads (23%) | called by muse, mutect2, varscan2
- LAMB2 | c.4999C>T p.L1667= | Silent (SNP) | VAF 53/225 reads (24%) | catalogued as rs926172016; called by muse, mutect2, varscan2
- LAMB2 | c.4998C>T p.L1666= | Silent (SNP) | VAF 52/224 reads (23%) | catalogued as rs143723352; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMB2 | c.1873C>T p.L625= | Silent (SNP) | VAF 27/172 reads (16%) | catalogued as rs569372725; called by muse, mutect2, varscan2
- LAMC3 | c.1020G>A p.R340= | Silent (SNP) | VAF 41/176 reads (23%) | called by muse, mutect2, varscan2
- LLGL2 | c.2619C>T p.I873= | Silent (SNP) | VAF 39/236 reads (17%) | called by muse, mutect2, varscan2
- LPO | c.651C>T p.F217= | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as COSV99228569; called by muse, mutect2, varscan2
- LRFN5 | c.264T>C p.S88= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV99981813, COSV99982901; called by muse, mutect2, varscan2
- MAP3K6 | c.1587C>T p.V529= | Silent (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- MEP1A | c.18C>T p.S6= | Silent (SNP) | VAF 16/115 reads (14%) | called by muse, mutect2, varscan2
- METTL7A | c.714C>T p.I238= | Silent (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- MUC4 | c.14859G>A p.P4953= (on ENST00000463781 / NM_018406.7; = p.P717= on NM_004532.6) | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as rs760409920; called by muse, mutect2, varscan2
- MYLK4 | c.135G>A p.Q45= | Silent (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- NDUFAF8 | c.12C>T p.N4= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs952593458; called by muse, mutect2, varscan2
- OPRPN | c.594A>T p.A198= | Silent (SNP) | VAF 24/274 reads (9%) | catalogued as COSV68193777; called by muse, mutect2
- OSBPL6 | c.1848G>A p.S616= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs200622460, COSV99506584; called by muse, mutect2, varscan2
- PAK5 | c.9G>A p.G3= | Silent (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- PAPPA | c.4227T>C p.A1409= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs138456310; called by muse, mutect2, varscan2
- PCDH19 | c.3252C>T p.T1084= (on ENST00000373034 / NM_001184880.2; = p.T1036= on NM_020766.3) | Silent (SNP) | VAF 40/280 reads (14%) | catalogued as COSV99720355; called by muse, varscan2
- PCDH9 | c.3646C>T p.L1216= (on ENST00000377865 / NM_203487.3; = p.L1182= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/153 reads (7%) | called by muse, mutect2
- PTPRZ1 | c.4740G>A p.G1580= | Silent (SNP) | VAF 26/202 reads (13%) | catalogued as COSV66437464; called by muse, mutect2, varscan2
- RELN | c.7542T>A p.L2514= | Silent (SNP) | VAF 24/159 reads (15%) | called by muse, mutect2, varscan2
- RYR2 | c.10389C>T p.T3463= | Silent (SNP) | VAF 31/152 reads (20%) | catalogued as rs878854151; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC6A19 | c.1566C>T p.I522= | Silent (SNP) | VAF 12/179 reads (7%) | catalogued as rs1317244914, COSV57254166; called by muse, mutect2
- SPTAN1 | c.3105C>T p.L1035= | Silent (SNP) | VAF 28/160 reads (18%) | catalogued as COSV63990131; called by muse, mutect2, varscan2
- TMEM132C | c.2607G>A p.V869= | Silent (SNP) | VAF 58/223 reads (26%) | catalogued as rs1426016111; called by muse, mutect2, varscan2
- TNFAIP2 | c.927C>T p.P309= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as COSV100280842; called by muse, mutect2, varscan2
- TOGARAM2 | c.2235C>T p.C745= | Silent (SNP) | VAF 14/181 reads (8%) | called by muse, mutect2
- TRBV20OR9-2 | c.108C>T p.V36= | Silent (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- TRPC7 | c.570C>T p.I190= | Silent (SNP) | VAF 37/198 reads (19%) | catalogued as COSV61464525; called by muse, mutect2, varscan2
- UBTFL1 | c.297T>C p.F99= | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- XIRP2 | c.2457C>T p.P819= (on ENST00000628543; = p.P994= on NM_152381.6) | Silent (SNP) | VAF 42/187 reads (22%) | called by muse, mutect2, varscan2
- ZMAT1 | c.1137G>A p.Q379= | Silent (SNP) | VAF 48/251 reads (19%) | called by muse, mutect2, varscan2
- ZNF45 | c.1227C>T p.G409= | Silent (SNP) | VAF 41/228 reads (18%) | catalogued as COSV54192956; called by muse, mutect2, varscan2
- AC084121.3 | n.28C>A | RNA (SNP) | VAF 3/34 reads (9%) | catalogued as rs372287493; called by muse, mutect2
- AC241377.4 | n.123+272A>C | Intron (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.563A>G | RNA (SNP) | VAF 11/219 reads (5%) | catalogued as rs376203414, COSV71422844; called by muse, mutect2
- APOA2 | c.-25+26A>C | Intron (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- CDH18 | c.1630+28T>C | Intron (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- CEP164 | c.393+3153C>T | Intron (SNP) | VAF 14/210 reads (7%) | catalogued as rs1166900025; called by muse, mutect2
- EVPL | c.1537+18G>A | Intron (SNP) | VAF 35/178 reads (20%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3281G>T | Intron (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- PACRG | c.614-67799G>A | Intron (SNP) | VAF 12/166 reads (7%) | catalogued as rs1275209261; called by muse, mutect2
- PARP8 | c.91+409T>C | Intron (SNP) | VAF 41/224 reads (18%) | called by muse, mutect2, varscan2
- PRR12 | chr19:49595017 C>T | 5'Flank (SNP) | VAF 36/174 reads (21%) | catalogued as rs139548181; called by muse, mutect2, varscan2
- SMIM23 | c.434+56G>A | Intron (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
